Somatic mutation profile of tumor specimen C3L-02650-05 (aliquot CPT0204990006) from CPTAC case C3L-02650, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.2 years (19,414 days).
Specimen C3L-02650-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c882e93-6652-494f-9fbb-a404143f2498.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02650-31 (Blood Derived Normal), aliquot CPT0205110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f788985d-526e-4652-89a5-f006ddef8675

The open-access MAF lists 261 somatic variants for this specimen: 190 protein-altering or splice-affecting, 41 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 41, Intron 14, Nonsense Mutation 10, Splice Site 8, Frame Shift Del 6, RNA 5, 5'UTR 4, 3'UTR 3, Frame Shift Ins 2, 3'Flank 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 124/681 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 104/324 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.2411G>T p.W804L | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51488665; called by muse, mutect2, varscan2
- ADAMTS18 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as COSV51422374; called by muse, mutect2
- C8orf34 | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.439); catalogued as rs777122735, COSV61397308; called by muse, mutect2, varscan2
- CACNA1E | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706379; called by muse, mutect2
- CCDC168 | c.17446G>T p.V5816F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as rs112284262; called by muse, mutect2, varscan2
- CDH12 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101202600; called by muse, mutect2, varscan2
- CDH9 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as COSV50273799; called by muse, mutect2, varscan2
- CDHR3 | c.2048C>A p.P683Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746142690; called by muse, mutect2, varscan2
- CPA5 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206801122, COSV62569436; called by muse, mutect2, varscan2
- CYP2C9 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV53246292; called by muse, mutect2, varscan2
- DMBT1 | c.5126G>T p.G1709V (on ENST00000338354 / NM_001377530.1; = p.G952V on NM_004406.3) | Missense Mutation (SNP) | VAF 64/604 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780570242; called by muse, mutect2, varscan2
- DMRTB1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758842237, COSV101008372; called by muse, mutect2, varscan2
- EHBP1L1 | c.4241A>G p.K1414R | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1327006993; called by muse, mutect2
- F5 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200765676, COSV63123049; called by muse, mutect2
- FAM160A2 | c.2205G>T p.Q735H (on ENST00000449352 / NM_001098794.2; = p.Q749H on NM_032127.4) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); catalogued as COSV56415354; called by muse, mutect2, varscan2
- FAM174B | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1005599116; called by muse, mutect2
- FAM83B | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1375505928; called by muse, mutect2, varscan2
- FBLN5 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 38/451 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50902166; called by muse, mutect2
- FRYL | c.3936G>A p.W1312* | Nonsense Mutation (SNP) | VAF 36/346 reads (10%) | catalogued as COSV51959243; called by muse, mutect2, varscan2
- GABRB3 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); catalogued as COSV100158191; called by muse, mutect2, varscan2
- GFRA2 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV100151354, COSV60780526; called by muse, mutect2, varscan2
- GLP2R | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV52327696; called by muse, mutect2
- IGKV3-11 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481191559; called by muse, mutect2
- IZUMO3 | c.605G>C p.R202P (on ENST00000543880 / NM_001365008.2; = p.R196P on NM_001271706.1) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV69048527; called by muse, mutect2, varscan2
- IZUMO3 | c.604C>T p.R202W (on ENST00000543880 / NM_001365008.2; = p.R196W on NM_001271706.1) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); catalogued as rs866465206, COSV69048158, COSV69048228, COSV69048750; called by muse, mutect2, varscan2
- KCNH8 | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1181263238, COSV60462796; called by muse, mutect2, varscan2
- KIF2B | c.1672G>T p.G558* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV52130762, COSV52136291; called by muse, mutect2
- KSR1 | c.1698G>T p.W566C (on ENST00000644974 / NM_001367810.1; = p.W451C on NM_014238.2) | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs758889494; called by muse, mutect2, varscan2
- LAG3 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 49/552 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201858640; called by muse, mutect2
- LASP1 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 14/225 reads (6%) | catalogued as COSV100530339; called by muse, mutect2
- MBD5 | c.3329G>A p.S1110N | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs778809485; called by muse, mutect2, varscan2
- MUC17 | c.9419C>G p.T3140S | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100071122; called by muse, mutect2, varscan2
- MYH1 | c.3835G>T p.A1279S | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99877389; called by muse, mutect2, varscan2
- MYO7B | c.5806G>T p.G1936C | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs943479943; called by muse, mutect2
- NEURL4 | c.2821C>T p.H941Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375446661; called by muse, mutect2, varscan2
- NEUROD6 | c.594C>A p.H198Q | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.722); catalogued as rs1310086728; called by muse, mutect2, varscan2
- OR1L4 | c.716T>C p.F239S | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328575175; called by muse, mutect2
- OR2T2 | c.108T>A p.F36L | Missense Mutation (SNP) | VAF 52/1312 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100737732; called by muse, mutect2
- OR2T2 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 63/1082 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1319299778; called by muse, mutect2
- OR2T29 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV60771696; called by muse, mutect2
- OR4N2 | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV60051203, COSV60053350; called by muse, mutect2
- PCDH15 | c.4639G>T p.G1547C (on ENST00000644397 / NM_001354429.2; = p.G1496C on NM_001142769.3) | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV64688259; called by muse, mutect2, varscan2
- PCDHB16 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs1554282168, COSV53367791; called by muse, mutect2, varscan2
- PEDS1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs199724655; called by muse, mutect2, varscan2
- PEG3 | c.4450G>T p.G1484C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55646176, COSV99686845; called by muse, mutect2, varscan2
- PGBD5 | c.820G>T p.G274W (on ENST00000525115; = p.G343W on NM_001258311.2) | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58410968; called by muse, mutect2
- POP1 | c.2774G>T p.R925L | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs756634206, COSV100855779; called by muse, mutect2, varscan2
- PRDM9 | c.209del p.R70Hfs*39 | Frame Shift Del (DEL) | VAF 35/396 reads (9%) | catalogued as COSV57005322, COSV57010207; called by mutect2, pindel
- PRKAR1B | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs762351800; called by muse, mutect2, varscan2
- PTH | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV56378824; called by muse, mutect2
- PTPRQ | c.1169G>T p.R390L (on ENST00000616559; = p.R348L on NM_001145026.2) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs775296221, COSV57050741; called by muse, mutect2
- PTPRT | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV61987709; called by muse, mutect2, varscan2
- RADX | c.1142T>C p.L381S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV65319794; called by muse, mutect2, varscan2
- REG3A | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59412453; called by muse, mutect2, varscan2
- REM1 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs141530884; called by muse, mutect2, varscan2
- RPS19BP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.736); catalogued as COSV58180352, COSV58180472; called by muse, mutect2, varscan2
- SALL3 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs779215862, COSV101610101; called by muse, mutect2, varscan2
- SDK1 | c.5336C>T p.S1779L | Missense Mutation (SNP) | VAF 87/515 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs775327865, COSV67372135; called by muse, mutect2, varscan2
- SLC17A3 | c.815del p.G272Efs*9 | Frame Shift Del (DEL) | VAF 48/238 reads (20%) | catalogued as COSV100399210, COSV57760101; called by mutect2, pindel, varscan2
- SLC9A4 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV54839886; called by muse, mutect2
- SYNE3 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs750448277; called by muse, mutect2, varscan2
- TP53 | c.1101-1G>T p.X367_splice | Splice Site (SNP) | VAF 18/296 reads (6%) | catalogued as COSV53196286; called by muse, mutect2
- TRAF3IP3 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1297891337; called by muse, mutect2
- TRIO | c.7666A>G p.M2556V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.347); catalogued as rs955511080; called by muse, varscan2
- WNT8A | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | catalogued as rs1481149249; called by muse, mutect2, varscan2
- ZNF257 | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs749346256, COSV71306372; called by muse, varscan2
- ZP4 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV63912203; called by muse, mutect2, varscan2
- ABCG5 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 30/229 reads (13%) | called by muse, mutect2, varscan2
- ABLIM3 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAP3 | c.429del p.R144Gfs*72 | Frame Shift Del (DEL) | VAF 43/277 reads (16%) | called by mutect2, pindel, varscan2
- ACE | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- ADAM19 | c.2405C>A p.S802Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADAMTS12 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADAMTS7 | c.2146G>T p.G716W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGAP5 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ALS2 | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.6703G>T p.G2235C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP39 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASTN1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP7A | c.2358G>T p.M786I | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATR | c.7780G>T p.D2594Y | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- BIVM-ERCC5 | c.3244G>T p.G1082C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CACNG8 | c.396_397insT p.I133Yfs*3 | Frame Shift Ins (INS) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- CCDC185 | c.450dup p.G151Rfs*69 | Frame Shift Ins (INS) | VAF 29/205 reads (14%) | called by mutect2, pindel, varscan2
- CCDC81 | c.1514C>A p.S505Y (on ENST00000445632 / NM_001156474.2; = p.S415Y on NM_021827.4) | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2
- CENPF | c.6484G>T p.E2162* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- CHRM2 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTNAP4 | c.1742G>T p.R581I | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- COL27A1 | c.3102G>T p.M1034I | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPA5 | c.534+1G>T p.X178_splice | Splice Site (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CR2 | c.1306_1308del p.K436del | In Frame Del (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- CSH2 | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CTNNA2 | c.298+2T>C p.X100_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | called by muse, varscan2
- CYP11B2 | c.1220T>G p.L407R | Missense Mutation (SNP) | VAF 67/547 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DCAF8L2 | c.1579G>T p.V527L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- DHX9 | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIP2B | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DIPK1B | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DLAT | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPP6 | c.986C>G p.P329R (on ENST00000377770 / NM_001364500.2; = p.P267R on NM_001936.5) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- F7 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.12); called by muse, mutect2
- FHOD1 | c.3212G>A p.R1071K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2
- FRMD6 | c.667G>C p.A223P (on ENST00000344768 / NM_001267046.2; = p.A215P on NM_152330.4) | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- FSIP2 | c.19129G>A p.E6377K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- GABRA2 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.578); called by muse, mutect2
- GLDC | c.635+1G>T p.X212_splice | Splice Site (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2IP | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GRID2IP | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GTF2H4 | c.474G>T p.V158= | Splice Region (SNP) | VAF 51/215 reads (24%) | called by muse, mutect2, varscan2
- HMCN1 | c.6700+2T>A p.X2234_splice | Splice Site (SNP) | VAF 14/169 reads (8%) | called by muse, mutect2
- KCNA4 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KCNA6 | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 119/514 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KCNH5 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF5A | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 37/444 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KLRF1 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KMT2D | c.4126A>G p.M1376V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- KRTAP10-4 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 40/763 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- KRTAP4-9 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LAMA2 | c.4138T>C p.C1380R | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN1 | c.161del p.K54Rfs*14 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- LRRC15 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC7 | c.1521T>A p.D507E (on ENST00000651989 / NM_001370785.2; = p.D474E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC74A | c.1424C>A p.T475K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LYPLA1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYSMD4 | c.779G>T p.G260V (on ENST00000409796 / NM_001284417.2; = p.G261V on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); called by muse, mutect2
- MASP1 | c.1741G>T p.G581* | Nonsense Mutation (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- MCUB | c.817-2A>G p.X273_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- MKKS | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH5 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYH2 | c.4313T>G p.V1438G | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MYO16 | c.2857A>G p.T953A | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NEU4 | c.350C>G p.T117R (on ENST00000391969 / NM_001167602.3; = p.T129R on NM_080741.4) | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- OR14A2 | c.932del p.A311Vfs*? | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- OR1C1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- OR1L6 | c.824T>C p.F275S (on ENST00000373684; = p.F239S on NM_001004453.2) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2M4 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR4E2 | c.786C>G p.D262E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR4K14 | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR4N2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 20/660 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2
- OR51B4 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- OR51F2 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOA | c.2123C>A p.A708E (on ENST00000286149; = p.A694E on NM_144672.4) | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PCDHGB2 | c.1352T>G p.V451G | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PFKP | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP4K2B | c.364A>T p.T122S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); called by muse, mutect2
- PLA2G4A | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL2 | c.3128G>T p.G1043V (on ENST00000615277 / NM_001144382.2; = p.G917V on NM_015184.5) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.356); called by muse, mutect2
- PLG | c.753C>A p.N251K | Missense Mutation (SNP) | VAF 106/434 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POU4F3 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PPP4R3C | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRPF19 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2
- PSG6 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRH | c.1040C>G p.A347G | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- R3HDM4 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- RAPGEF2 | c.4291G>T p.A1431S | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- RASAL2 | c.1835T>C p.I612T | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- RBM25 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- RIMS2 | c.1522C>A p.R508S (on ENST00000666250 / NM_001348490.2; = p.R316S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RRAGC | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCN8A | c.5137C>G p.P1713A | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK2 | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 42/407 reads (10%) | called by muse, mutect2, varscan2
- SHOX | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SIDT1 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A5 | c.1414T>A p.S472T (on ENST00000454036 / NM_001134771.2; = p.S449T on NM_020708.5) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLCO1B1 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATS1 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SPTBN2 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 44/562 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2
- SUPT7L | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIP | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TARBP1 | c.377_419del p.R126Pfs*5 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel
- TBC1D12 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2
- TNFRSF11A | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TRPM2 | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- TSHZ2 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSKS | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBE3B | c.1957-1G>T p.X653_splice | Splice Site (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- UGT2A3 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- UROC1 | c.1247C>A p.A416E | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- VCX3A | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- WDR88 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- WFS1 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZNF234 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF611 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ZNF713 | c.655G>T p.E219* (on ENST00000633730 / NM_001366796.2; = p.E232* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- ZNF765 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADGRB2 | c.3960G>A p.E1320= | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3369C>T p.H1123= (on ENST00000611781; = p.H1067= on NM_052997.2) | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- BAMBI | c.582G>A p.L194= | Silent (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- BEST1 | c.6C>A p.T2= | Silent (SNP) | VAF 48/480 reads (10%) | called by muse, mutect2
- BRINP2 | c.1356C>T p.C452= | Silent (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
- CPXCR1 | c.465G>A p.L155= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CSMD2 | c.120A>T p.P40= | Silent (SNP) | VAF 30/448 reads (7%) | catalogued as rs1188414865; called by muse, mutect2
- DLAT | c.1272A>T p.P424= | Silent (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- DNAH3 | c.4014G>T p.G1338= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV54520261, COSV54534174; called by muse, mutect2, varscan2
- DRD2 | c.96C>A p.P32= | Silent (SNP) | VAF 46/379 reads (12%) | called by muse, mutect2, varscan2
- FOXB2 | c.489C>A p.P163= | Silent (SNP) | VAF 38/161 reads (24%) | called by mutect2, varscan2
- FSIP2 | c.15453G>T p.V5151= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- FZD10 | c.972G>T p.S324= | Silent (SNP) | VAF 54/287 reads (19%) | catalogued as rs1230625132; called by muse, mutect2, varscan2
- GATA6 | c.669C>T p.P223= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- GINS3 | c.150G>C p.R50= | Silent (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- GLB1L3 | c.171C>A p.T57= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- KCNK9 | c.1068T>G p.P356= | Silent (SNP) | VAF 83/490 reads (17%) | catalogued as rs759064977; called by muse, mutect2, varscan2
- MYCBPAP | c.1305C>T p.G435= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs777887197, COSV60409140; called by muse, mutect2
- MYH7 | c.1542C>A p.G514= | Silent (SNP) | VAF 60/515 reads (12%) | catalogued as rs1215137868; called by muse, mutect2, varscan2
- NAV3 | c.6978C>A p.S2326= (on ENST00000397909 / NM_001024383.2; = p.S2304= on NM_014903.6) | Silent (SNP) | VAF 40/300 reads (13%) | called by muse, mutect2, varscan2
- NDN | c.423G>T p.R141= | Silent (SNP) | VAF 21/193 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.5820G>A p.L1940= | Silent (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- NKAPL | c.252G>C p.A84= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV59198314; called by muse, mutect2, varscan2
- NPEPL1 | c.60G>T p.R20= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- NRG1 | c.51G>T p.V17= (on ENST00000523534; = p.V164= on NM_013962.2) | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV73066029; called by muse, mutect2, varscan2
- OR51B4 | c.312G>T p.L104= | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as COSV100970524; called by muse, mutect2
- PROK1 | c.117C>T p.A39= | Silent (SNP) | VAF 53/381 reads (14%) | catalogued as rs909508876; called by muse, mutect2, varscan2
- SLC24A3 | c.546C>G p.T182= | Silent (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.744G>T p.P248= | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as rs370494405, COSV57793610, COSV57796058; called by muse, mutect2, varscan2
- STOML3 | c.789G>T p.T263= | Silent (SNP) | VAF 34/326 reads (10%) | catalogued as COSV65511105; called by muse, mutect2
- SUGCT | c.1293G>T p.V431= (on ENST00000335693 / NM_001193313.2; = p.V457= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV59349445; called by muse, mutect2, varscan2
- TMEM219 | c.231A>T p.T77= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2
- TRBV3-1 | c.90G>A p.L30= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs775283475; called by muse, varscan2
- TRIM48 | c.309C>T p.S103= | Silent (SNP) | VAF 28/424 reads (7%) | called by muse, mutect2
- TUBA3E | c.702C>A p.I234= | Silent (SNP) | VAF 54/352 reads (15%) | catalogued as COSV56058758; called by muse, mutect2, varscan2
- USP6 | c.843C>T p.T281= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as rs1442387122; called by muse, mutect2, varscan2
- UTY | c.3234A>T p.T1078= | Silent (SNP) | VAF 32/124 reads (26%) | called by muse, mutect2, varscan2
- UVSSA | c.1950G>A p.G650= | Silent (SNP) | VAF 16/237 reads (7%) | catalogued as rs778999089; called by muse, mutect2
- WIPF3 | c.720C>A p.A240= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- ZIC1 | c.414G>T p.A138= | Silent (SNP) | VAF 91/364 reads (25%) | catalogued as COSV51558412; called by muse, mutect2, varscan2
- ZNF716 | c.435T>A p.V145= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1462853818; called by muse, mutect2, varscan2
- AC073310.1 | n.152G>T | RNA (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- ARHGAP5 | c.-204C>A | 5'UTR (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- ARHGEF4 | c.-108-166G>T | Intron (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- CARD8 | c.351-908C>T | Intron (SNP) | VAF 9/89 reads (10%) | catalogued as rs573503983; called by muse, mutect2, varscan2
- CD59 | c.*49G>T | 3'UTR (SNP) | VAF 55/290 reads (19%) | catalogued as rs181012235; called by muse, mutect2, varscan2
- COPS4 | c.75-13G>T | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- COPS4 | c.75-12G>T | Intron (SNP) | VAF 4/72 reads (6%) | catalogued as rs942721646; called by muse, mutect2
- DNAH14 | c.1032+1209G>C | Intron (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100835939; called by muse, mutect2
- FGD4 | c.167-78001G>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- GRIN2C | chr17:74860496 G>A | 5'Flank (SNP) | VAF 49/350 reads (14%) | catalogued as COSV99500708; called by muse, mutect2, varscan2
- HMGN2P46 | n.1159T>C | RNA (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- HSPB6 | c.*39C>G | 3'UTR (SNP) | VAF 16/89 reads (18%) | catalogued as rs915786699; called by muse, mutect2, varscan2
- MAGEB5 | c.-1C>A | 5'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- MILR1 | chr17:64468355 C>A | 3'Flank (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- MIR889 | n.51A>T | RNA (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099270 C>A | 3'Flank (SNP) | VAF 16/414 reads (4%) | called by muse, mutect2
- MUCL3 | c.946+1025A>G | Intron (SNP) | VAF 66/339 reads (19%) | called by muse, mutect2, varscan2
- NKAIN3 | c.-79C>A | 5'UTR (SNP) | VAF 47/269 reads (17%) | called by muse, mutect2, varscan2
- NPAS3 | c.558+52198C>A | Intron (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- POLN | c.*110G>T | 3'UTR (SNP) | VAF 27/392 reads (7%) | catalogued as COSV59050984; called by muse, mutect2
- PRR12 | c.51+216G>T | Intron (SNP) | VAF 14/112 reads (13%) | catalogued as COSV55869924; called by muse, mutect2, varscan2
- PRSS1 | c.200+407T>G | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- RN7SL106P | chr15:23164033 A>T | 5'Flank (SNP) | VAF 56/442 reads (13%) | called by muse, varscan2
- SCNN1A | c.1498-34G>C | Intron (SNP) | VAF 25/462 reads (5%) | called by muse, mutect2
- SIDT2 | c.1420-13G>C | Intron (SNP) | VAF 23/154 reads (15%) | catalogued as rs1403238820; called by muse, mutect2, varscan2
- SSPOP | n.10074C>T | RNA (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- SUGT1P4-STRA6LP | n.896del | RNA (DEL) | VAF 24/185 reads (13%) | called by mutect2, pindel, varscan2
- USP28 | c.1059+323del | Intron (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- WT1 | c.1304-51C>G | Intron (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- ZNF730 | c.-16C>A | 5'UTR (SNP) | VAF 18/178 reads (10%) | catalogued as COSV101649195; called by muse, mutect2
